Gene-level copy-number profile of specimen HCM-CSHL-0814-C54-85A from HCMI case HCM-CSHL-0814-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage IIIC; Tumor grade: G3.
Specimen HCM-CSHL-0814-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7fc06bc1-c116-4e99-9b19-b6cb3070cccd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0814-C54-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,240 have no estimate.
https://portal.gdc.cancer.gov/files/0a2ef6ca-c2a8-4eb4-82c1-7ce0edbcc7c7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,632; copy number 2: 17,183; copy number 3: 24,398; copy number 4: 10,212; copy number 5: 2,633; copy number 6: 1,238; copy number 7: 604; copy number 8: 182; copy number 9: 71; copy number 10: 225; copy number 11: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,087 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:32,354,350–32,444,740, 2 genes, copy number 7: ZFR, MIR579.
- chr5:37,085,056–37,130,700, 2 genes, copy number 7: RPS4XP6, RBISP2.
- chr5:37,249,026–37,252,617, 1 gene, copy number 7: AC025449.2.
- chr6:60,281,444–71,652,611, 97 genes, copy number 7–9 (broad region; genes not listed).
- chr8:40,900,016–42,844,876, 49 genes, copy number 7: AC048387.1, RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1.
- chr8:46,028,804–46,028,892, 1 gene, copy number 7: AC118650.1.
- chr8:46,697,630–54,420,725, 119 genes, copy number 8 (broad region; genes not listed).
- chr8:55,102,028–55,542,054, 5 genes, copy number 7 (within-gene range 7–9): XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1.
- chr8:93,213,302–93,700,433, 1 gene, copy number 7 (within-gene range 5–7): LINC00535.
- chr8:93,259,667–95,811,254, 60 genes, copy number 7 (within-gene range 3–7): AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2, C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1.
- chr8:99,873,200–104,589,024, 118 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:111,376,639–113,950,998, 12 genes, copy number 8: LINC02237, SERPINA15P, H2AZP7, RNU4-37P, CSMD3, AC024996.1, RPL30P16, MIR2053, AC107890.1, AC055788.2, AC103993.1, Y_RNA.
- chr8:117,265,272–118,622,112, 7 genes, copy number 10–11 (within-gene range 5–11): AC084114.1, AP002848.1, MED30, RPS10P16, EXT1, SAMD12, AC023590.1.
- chr8:131,904,093–134,979,279, 54 genes, copy number 7: EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56.
- chr8:138,588,235–139,127,953, 4 genes, copy number 7: COL22A1, AC027541.1, AC100807.1, AC100807.2.
- chr8:139,508,701–144,080,648, 137 genes, copy number 7–10 (broad region; genes not listed).
- chr12:28,821,975–34,249,958, 118 genes, copy number 7–9 (broad region; genes not listed).
- chr12:54,121,277–54,687,434, 31 genes, copy number 7–9 (within-gene range 4–9): SMUG1, LINC02381, AC023794.5, AC023794.4, AC023794.1, CBX5, MIR3198-2, RN7SL390P, SCAT2, AC078778.1, HNRNPA1, NFE2, COPZ1, RNU6-950P, MIR148B, RN7SL744P, AC079313.2, AC079313.1, GPR84, ZNF385A, ITGA5, LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1.
- chr12:62,466,817–62,600,476, 1 gene, copy number 10 (within-gene range 4–10): MON2.
- chr12:62,545,582–72,186,618, 209 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr14:102,139,503–103,057,549, 19 genes, copy number 8 (within-gene range 4–8): WDR20, MOK, ZNF839, CINP, TECPR2, RNU6-244P, ANKRD9, MIR4309, LINC02323, RN7SL546P, RCOR1, RPL23AP11, Y_RNA, AL132801.1, TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1.
- chr14:105,209,286–105,470,729, 8 genes, copy number 7 (within-gene range 5–7): BRF1, BTBD6, PACS2, AL928654.4, RPS20P33, TEX22, AL928654.1, MTA1.
- chr16:10,928,891–10,942,468, 2 genes, copy number 9 (within-gene range 2–9): DEXI, AC133065.3.
- chr16:11,926,199–11,976,643, 2 genes, copy number 7 (within-gene range 5–7): AC007216.5, NPIPB2.
- chr17:18,450,244–18,551,705, 9 genes, copy number 7–8 (within-gene range 4–8): KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr21:10,122,273–10,358,620, 5 genes, copy number 8: CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P.
- chr22:21,354,563–21,551,461, 14 genes, copy number 7 (within-gene range 6–7): LINC01651, AP000552.1, Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP, HIC2, Metazoa_SRP, TMEM191C, PI4KAP2, AP000557.1, RN7SKP221, RIMBP3C.

Autosomal genes at a single copy (total copy number 1): 1,632. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
